Somatic mutation profile of tumor specimen TCGA-DR-A0ZM-01A (aliquot TCGA-DR-A0ZM-01A-12D-A10S-08) from TCGA case TCGA-DR-A0ZM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.5 years (22,464 days).
Specimen TCGA-DR-A0ZM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d67f65d-b03c-48a1-a131-d41698f76637.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DR-A0ZM-10A (Blood Derived Normal), aliquot TCGA-DR-A0ZM-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f9df227-ca85-44cc-9ced-336db1b7b99f

The open-access MAF lists 1,429 somatic variants for this specimen: 1,058 protein-altering or splice-affecting, 340 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 917, Silent 340, Nonsense Mutation 102, Splice Site 14, Splice Region 12, Intron 9, RNA 9, 5'UTR 6, Frame Shift Del 6, 5'Flank 4, Nonstop Mutation 3, Translation Start Site 3.

Variants (750 of 1,429; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENG | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | catalogued as rs1564462827, CM060981, COSV61227917; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as rs962041031, CM040077; ClinVar: likely pathogenic; called by muse, varscan2
- KCNQ2 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs727503974, CM120572, COSV60435951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 28/149 reads (19%) | catalogued as rs63749917, CM052255, COSV51881210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHEX | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 55/221 reads (25%) | catalogued as rs770573978, CM971148, COSV65076754; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATF | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 54/323 reads (17%) | catalogued as rs1045523068; called by muse, varscan2
- ABCA10 | c.693G>C p.M231I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV52225327; called by muse, mutect2, varscan2
- ABCC5 | c.2794C>T p.R932* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as rs1479942268, COSV55592708; called by muse, mutect2, varscan2
- ABCC8 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV56853059; called by muse, mutect2
- ABCD4 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs1425390688, COSV53993217; called by muse, mutect2, varscan2
- ABCF3 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as COSV53053385, COSV99491452; called by muse, mutect2, varscan2
- ACADVL | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 33/179 reads (18%) | catalogued as COSV50037038; called by muse, mutect2, varscan2
- ACE | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs750545791, COSV52009129; called by muse, mutect2, varscan2
- ACKR1 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV63673437; called by muse, mutect2, varscan2
- ACLY | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs782078720, COSV61251381; called by muse, mutect2
- ACOT12 | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV56896040, COSV56898447; called by muse, mutect2, varscan2
- ACSS2 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53625787, COSV53628459; called by muse, mutect2, varscan2
- ACTL10 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs370919410, COSV55777051; called by muse, mutect2, varscan2
- ADAM15 | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772653499, COSV55127995; called by muse, mutect2, varscan2
- ADAMTS9 | c.4753G>C p.D1585H | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55784525; called by muse, mutect2, varscan2
- ADCY1 | c.936C>G p.F312L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV52037309; called by muse, mutect2, varscan2
- ADCY10 | c.1476G>C p.E492D | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV63242138, COSV63245479; called by muse, mutect2
- ADCY7 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202891173, COSV54264517; called by muse, mutect2, varscan2
- ADGRG2 | c.352G>A p.D118N (on ENST00000379869 / NM_001079858.3; = p.D115N on NM_005756.4) | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.005); catalogued as COSV61339964; called by muse, mutect2, varscan2
- ADGRG5 | c.819C>T p.F273= | Splice Region (SNP) | VAF 18/75 reads (24%) | catalogued as COSV61083794; called by muse, mutect2, varscan2
- ADGRL1 | c.3665-1G>A p.X1222_splice (on ENST00000340736 / NM_001008701.3; = p.X1217_splice on NM_014921.5) | Splice Site (SNP) | VAF 12/140 reads (9%) | catalogued as COSV61565384; called by muse, mutect2
- ADGRL1 | c.1582G>A p.D528N (on ENST00000340736 / NM_001008701.3; = p.D523N on NM_014921.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV61565389; called by muse, mutect2, varscan2
- ADGRV1 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV67988980; called by muse, mutect2
- ADH4 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV55501309; called by muse, mutect2, varscan2
- ADRM1 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV53363848; called by muse, mutect2
- AFF1 | c.2780C>T p.S927L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs140882176; called by muse, mutect2, varscan2
- AGAP2 | c.2902G>C p.E968Q (on ENST00000547588 / NM_001122772.2; = p.E612Q on NM_014770.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV57729521; called by muse, mutect2, varscan2
- AGO4 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV64617708; called by muse, mutect2, varscan2
- AHCTF1 | c.4177G>C p.D1393H (on ENST00000366508; = p.D1367H on NM_015446.5) | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1558222072, COSV58251991; called by muse, mutect2, varscan2
- AHCTF1 | c.1405G>C p.E469Q (on ENST00000366508; = p.E443Q on NM_015446.5) | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV58252000; called by muse, mutect2, varscan2
- AHNAK2 | c.11740G>C p.D3914H | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60920407; called by muse, mutect2, varscan2
- AIFM3 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV53148764; called by muse, mutect2, varscan2
- AKAP6 | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55219892; called by muse, mutect2, varscan2
- AKAP8 | c.1997G>C p.R666T | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.005); catalogued as COSV54103318; called by muse, mutect2, varscan2
- AKNA | c.3853G>A p.G1285S | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV56338139, COSV99801268; called by muse, mutect2, varscan2
- AKT3 | c.1212C>G p.F404L | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55621735, COSV55629831; called by muse, mutect2, varscan2
- ALDH8A1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55642712; called by muse, mutect2, varscan2
- ALG1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as rs765599429, COSV52158255; called by muse, mutect2, varscan2
- AMDHD1 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV57139398; called by muse, mutect2, varscan2
- AMY2B | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 55/511 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV63715967, COSV63716962; called by muse, mutect2, varscan2
- ANGEL1 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 105/488 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV51874130; called by muse, mutect2, varscan2
- ANK2 | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52170793; called by muse, mutect2, varscan2
- ANKFN1 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV59451781, COSV59460240; called by muse, mutect2, varscan2
- ANKRD22 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV64236867; called by muse, mutect2, varscan2
- ANKRD26 | c.4947G>C p.L1649F | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV65776479; called by muse, mutect2, varscan2
- ANKS1A | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 95/434 reads (22%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.977); catalogued as rs1398631801, COSV64462004; called by muse, mutect2, varscan2
- ANKS1A | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64462008; called by muse, mutect2, varscan2
- ANKZF1 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as COSV55477329; called by muse, mutect2
- ANOS1 | c.1375C>G p.H459D | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.28); catalogued as COSV52922197; called by muse, mutect2, varscan2
- AOPEP | c.1921G>C p.E641Q (on ENST00000375315 / NM_001193329.1; = p.E542Q on NM_032823.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV52993339; called by muse, mutect2
- AP3S1 | c.327G>C p.L109F | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57475486; called by muse, mutect2, varscan2
- APLP2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV53841895; called by muse, mutect2, varscan2
- APOA4 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 76/296 reads (26%) | catalogued as COSV63360691; called by muse, mutect2, varscan2
- APOB | c.11404C>G p.Q3802E | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51941702; called by muse, mutect2, varscan2
- APOB | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV51941714; called by muse, mutect2, varscan2
- APOB | c.2479C>G p.L827V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.997); catalogued as COSV51941726; called by muse, mutect2, varscan2
- APOBEC3B | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59841491; called by muse, mutect2, varscan2
- APPL2 | c.422A>C p.D141A | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV51591596; called by muse, mutect2, varscan2
- AQR | c.3556C>T p.Q1186* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV50038950; called by muse, mutect2, varscan2
- ARFGEF2 | c.5184C>G p.F1728L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV64213336; called by muse, mutect2, varscan2
- ARHGAP30 | c.2689G>A p.E897K (on ENST00000368013 / NM_001025598.2; = p.E686K on NM_181720.3) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as COSV63517450; called by muse, mutect2, varscan2
- ARHGAP30 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 83/510 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as COSV63517458; called by muse, mutect2, varscan2
- ARHGAP44 | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV52396313; called by muse, mutect2, varscan2
- ARHGEF2 | c.961C>G p.L321V (on ENST00000361247 / NM_001162383.2; = p.L293V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.194); catalogued as COSV58112960; called by muse, mutect2, varscan2
- ARHGEF3 | c.1580G>C p.*527Sext*60 | Nonstop Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV56328736; called by muse, mutect2, varscan2
- ARHGEF4 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58124892; called by muse, mutect2, varscan2
- ARMC4 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV59466892; called by muse, mutect2, varscan2
- ARMT1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401676243, COSV66178737; called by muse, mutect2, varscan2
- ASPH | c.338C>G p.S113C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.81); catalogued as COSV62860173; called by muse, mutect2, varscan2
- ASPN | c.977G>C p.R326T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65016321; called by muse, mutect2, varscan2
- ASTN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV56074519; called by muse, mutect2
- ATG2B | c.5545G>A p.E1849K | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55891171; called by muse, mutect2, varscan2
- ATP11A | c.2749C>G p.L917V | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV52115782; called by muse, mutect2, varscan2
- ATP11B | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV60030267; called by muse, mutect2, varscan2
- ATP13A1 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV52288066; called by muse, mutect2, varscan2
- ATP1B3 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs768861940, COSV53950387; called by muse, mutect2, varscan2
- ATP2B1 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.797); catalogued as COSV53809621; called by muse, mutect2
- ATP2B2 | c.2823G>A p.M941I (on ENST00000352432; = p.M907I on NM_001683.5) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV59500499; called by muse, mutect2, varscan2
- ATP5PF | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV53167364; called by muse, mutect2, varscan2
- ATP8A1 | c.2401G>C p.D801H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52539429; called by muse, mutect2, varscan2
- ATRNL1 | c.3612C>G p.F1204L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58096097; called by muse, mutect2, varscan2
- AURKA | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV57168987; called by muse, mutect2, varscan2
- B2M | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.024); catalogued as COSV62564998, COSV62566466; called by muse, mutect2, varscan2
- B3GLCT | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV58456358; called by muse, mutect2, varscan2
- B4GALT3 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV60527490; called by muse, mutect2, varscan2
- BAZ1B | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.398); catalogued as COSV59992237; called by muse, mutect2, varscan2
- BAZ2A | c.4726C>T p.Q1576* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV51639066; called by muse, mutect2, varscan2
- BAZ2A | c.4122C>G p.F1374L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51639094; called by muse, mutect2, varscan2
- BAZ2A | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 60/327 reads (18%) | catalogued as COSV51639122; called by muse, mutect2, varscan2
- BAZ2B | c.5668G>C p.E1890Q | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV58604363; called by muse, mutect2, varscan2
- BCAN | c.1913G>T p.R638L | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61257716; called by muse, mutect2, varscan2
- BCL9 | c.758G>C p.R253T | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs942590817, COSV52346611; called by muse, mutect2, varscan2
- BCL9L | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52686296; called by muse, mutect2, varscan2
- BCOR | c.2272C>A p.P758T | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV60711367; called by muse, mutect2, varscan2
- BCR | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 29/196 reads (15%) | catalogued as COSV59933233; called by muse, varscan2
- BDP1 | c.6149C>G p.S2050C | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV62432379; called by muse, mutect2, varscan2
- BEGAIN | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1225779940, COSV62069306; called by muse, mutect2, varscan2
- BEND4 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs777896000, COSV72469202; called by muse, mutect2, varscan2
- BHLHE40 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs749055581, COSV56575863; called by muse, varscan2
- BIK | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs532663391, COSV51792892, COSV51794081; called by muse, mutect2, varscan2
- BLM | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV61924312, COSV61925186; called by muse, mutect2, varscan2
- BMI1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV64958851; called by muse, mutect2, varscan2
- BMPR1B | c.1247C>G p.S416* | Nonsense Mutation (SNP) | VAF 42/186 reads (23%) | catalogued as COSV52779146; called by muse, mutect2, varscan2
- BOD1L1 | c.2189G>C p.R730T | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV50022634; called by muse, varscan2
- BORA | c.724G>C p.E242Q (on ENST00000613797; = p.E167Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64695494; called by muse, mutect2, varscan2
- BRAP | c.245-1G>C p.X82_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as COSV58159034; called by muse, mutect2, varscan2
- BRCA1 | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58793450; called by muse, mutect2, varscan2
- BRCC3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57463069; called by muse, mutect2, varscan2
- BROX | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61799494; called by muse, mutect2
- BRPF1 | c.1434G>T p.W478C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as COSV57406052; called by muse, mutect2
- BRPF1 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57406068; called by muse, mutect2, varscan2
- BRPF3 | c.371C>G p.S124* | Nonsense Mutation (SNP) | VAF 36/175 reads (21%) | catalogued as COSV60208187; called by muse, mutect2, varscan2
- BRWD1 | c.461G>C p.R154P | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV58123132; called by muse, mutect2, varscan2
- BSN | c.7924G>A p.D2642N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV56521676; called by muse, mutect2, varscan2
- BTAF1 | c.2743C>G p.P915A | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV56435985; called by muse, mutect2, varscan2
- BTBD10 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as rs75019394, COSV53400029; called by muse, varscan2
- BZW2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV51755907, COSV51757631; called by muse, mutect2, varscan2
- C12orf43 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C1orf112 | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as COSV53680267; called by muse, mutect2, varscan2
- C2CD3 | c.4612C>G p.P1538A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58094946; called by muse, mutect2, varscan2
- C9orf131 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56612243; called by muse, mutect2, varscan2
- CA10 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.984); catalogued as COSV53357329; called by muse, mutect2, varscan2
- CA14 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV52529797, COSV99354578; called by muse, mutect2, varscan2
- CACNA1C | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV59738645; called by muse, mutect2, varscan2
- CACNA1C | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100223336, COSV59738660; called by muse, mutect2, varscan2
- CACNA1G | c.5086G>C p.E1696Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61731260; called by mutect2, varscan2
- CACNA1I | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs988674699, COSV60812317; called by muse, mutect2, varscan2
- CACNA2D1 | c.1731G>C p.K577N (on ENST00000356253 / NM_001366867.1; = p.K558N on NM_000722.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV62379072, COSV62383552; called by muse, mutect2, varscan2
- CAGE1 | c.1468G>A p.E490K (on ENST00000512086; = p.E354K on NM_205864.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1211732085, COSV57078688; called by muse, mutect2, varscan2
- CALCOCO2 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV51952591; called by muse, mutect2, varscan2
- CALD1 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62649698; called by muse, mutect2, varscan2
- CALM3 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52194603; called by muse, mutect2, varscan2
- CAPN3 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM092450, COSV58823943; called by muse, mutect2, varscan2
- CARF | c.734G>C p.W245S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV57548443; called by muse, mutect2, varscan2
- CARMIL3 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57727190; called by muse, mutect2, varscan2
- CASKIN1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779323369, COSV58873606; called by muse, mutect2, varscan2
- CAVIN2 | c.698G>C p.R233T | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV58424027, COSV58424701; called by muse, mutect2, varscan2
- CBWD5 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as rs371887218; called by mutect2, varscan2
- CCAR1 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV56271288; called by muse, mutect2
- CCDC125 | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV67288357; called by muse, mutect2, varscan2
- CCDC15 | c.531G>A p.M177I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61083001; called by muse, mutect2, varscan2
- CCDC7 | c.3796G>C p.D1266H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs768994985, COSV56545675; called by muse, mutect2
- CCDC77 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV53473350; called by muse, mutect2, varscan2
- CCNB3 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV52075720; called by muse, mutect2, varscan2
- CCNB3 | c.1512G>C p.L504F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV52075733; called by muse, mutect2, varscan2
- CCPG1 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV60526244; called by muse, mutect2, varscan2
- CCT2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1055658846, COSV54739146; called by muse, mutect2, varscan2
- CCT6B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs755333614, COSV58487981; called by muse, mutect2, varscan2
- CD163 | c.3302C>T p.S1101F | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.896); catalogued as COSV63134475, COSV63137975; called by muse, mutect2, varscan2
- CD200R1 | c.859G>A p.E287K (on ENST00000471858 / NM_170780.3; = p.E310K on NM_138806.4) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV55601864; called by muse, mutect2, varscan2
- CD226 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs763454639, COSV54613762; called by muse, mutect2, varscan2
- CDC42BPA | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62014215; called by muse, mutect2
- CDC42BPG | c.255C>T p.V85= | Splice Region (SNP) | VAF 67/207 reads (32%) | catalogued as COSV61348070; called by muse, mutect2, varscan2
- CDC73 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66468106; called by muse, mutect2, varscan2
- CDCP1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56106452; called by muse, mutect2, varscan2
- CDHR3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs545341223, COSV58418814; called by muse, mutect2, varscan2
- CDHR3 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58418824; called by muse, mutect2
- CDHR3 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58418842; called by muse, mutect2, varscan2
- CDK13 | c.4331C>T p.S1444F | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.191); catalogued as COSV51702591; called by muse, mutect2, varscan2
- CDK3 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV56912930; called by muse, mutect2, varscan2
- CDK5RAP3 | c.455C>A p.A152E | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.231); catalogued as COSV58115427; called by muse, mutect2, varscan2
- CEBPA | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57198244; called by muse, mutect2, varscan2
- CECR2 | c.2215C>G p.Q739E (on ENST00000342247 / NM_001290047.2; = p.Q556E on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52844121; called by muse, mutect2, varscan2
- CELSR2 | c.8022G>C p.K2674N | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV54774756; called by muse, mutect2, varscan2
- CEP104 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV65516676, COSV65518088; called by muse, mutect2, varscan2
- CEP120 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60266544; called by muse, mutect2, varscan2
- CEP152 | c.919C>G p.Q307E | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100359167, COSV57861073; called by muse, mutect2
- CEP85 | c.2155G>C p.D719H | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53330643; called by muse, mutect2, varscan2
- CEP89 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV59865495; called by muse, mutect2, varscan2
- CFAP54 | c.7888C>T p.Q2630* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV61573061; called by muse, mutect2, varscan2
- CFAP65 | c.5320G>C p.E1774Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV100444976, COSV58562867; called by muse, mutect2, varscan2
- CFTR | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV50068087; called by muse, mutect2, varscan2
- CHD6 | c.7753G>A p.E2585K | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV64692267; called by muse, mutect2, varscan2
- CHD7 | c.6097G>C p.D2033H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV71109754; called by muse, mutect2, varscan2
- CHD8 | c.4438G>C p.E1480Q (on ENST00000646647 / NM_001170629.2; = p.E1201Q on NM_020920.4) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV63219323; called by muse, mutect2
- CHD8 | c.4030G>A p.E1344K (on ENST00000646647 / NM_001170629.2; = p.E1065K on NM_020920.4) | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV63219328; called by muse, varscan2
- CHGA | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV53663698; called by muse, mutect2, varscan2
- CHKB | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56414831, COSV56417487; called by muse, mutect2, varscan2
- CHRNE | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.58); catalogued as COSV53418743; called by muse, mutect2, varscan2
- CHST4 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV58297596, COSV58298090; called by muse, mutect2, varscan2
- CHST5 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60340162; called by muse, mutect2, varscan2
- CIAPIN1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV67953450; called by muse, mutect2, varscan2
- CIB3 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54166817; called by muse, mutect2, varscan2
- CIZ1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV52972865; called by muse, mutect2, varscan2
- CLASP1 | c.2277G>C p.E759D | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as COSV55328996; called by muse, varscan2
- CLCA4 | c.1957G>C p.D653H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55369329; called by muse, mutect2, varscan2
- CLK3 | c.1827C>G p.I609M (on ENST00000395066 / NM_001130028.1; = p.I461M on NM_003992.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV59340857; called by muse, mutect2, varscan2
- CNBD2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as COSV62587294; called by muse, mutect2, varscan2
- CNIH1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV53594772; called by muse, mutect2, varscan2
- CNOT10 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV59393067, COSV59394922; called by muse, mutect2, varscan2
- CNTNAP3 | c.3043C>T p.Q1015* | Nonsense Mutation (SNP) | VAF 18/202 reads (9%) | catalogued as rs1213951290; called by muse, mutect2
- CNTNAP5 | c.1418C>A p.P473Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV70494026, COSV70519570; called by muse, mutect2, varscan2
- COBLL1 | c.1024C>T p.Q342* (on ENST00000392717; = p.Q304* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as COSV52070733; called by muse, mutect2, varscan2
- COCH | c.1801G>C p.D601H (on ENST00000216361 / NM_001347720.1; = p.D536H on NM_004086.3) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs1328002573, COSV53551587; called by muse, mutect2, varscan2
- COL6A3 | c.6334G>C p.D2112H | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55096008, COSV99797057; called by muse, mutect2
- COLEC12 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV68371813; called by muse, mutect2, varscan2
- CORO1B | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1463137475, COSV58169582, COSV58170515; called by muse, mutect2, varscan2
- CORO6 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.427); catalogued as rs1350495803, COSV100801249, COSV61471331; called by muse, mutect2, varscan2
- CORO7 | c.1392G>C p.Q464H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV52031710; called by muse, mutect2, varscan2
- CP | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52829706, COSV52831728; called by muse, mutect2, varscan2
- CPEB2 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); catalogued as COSV52592977; called by muse, mutect2, varscan2
- CPN1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV64942487; called by muse, mutect2, varscan2
- CPNE3 | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52207730; called by muse, mutect2, varscan2
- CPNE3 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52207740; called by muse, mutect2, varscan2
- CPPED1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs959295487, COSV55499006; called by muse, mutect2, varscan2
- CPZ | c.1178C>G p.S393C (on ENST00000360986 / NM_001014447.3; = p.S382C on NM_003652.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59923976; called by muse, mutect2, varscan2
- CRB1 | c.2129-1G>C p.X710_splice | Splice Site (SNP) | VAF 26/129 reads (20%) | catalogued as COSV66329889, COSV66331406; called by muse, mutect2, varscan2
- CRB2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63504110; called by muse, mutect2, varscan2
- CREBBP | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV52129634; called by muse, mutect2, varscan2
- CREBZF | c.896C>G p.S299W | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV52630083; called by muse, mutect2, varscan2
- CRMP1 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1390300757, COSV61481283; called by muse, mutect2, varscan2
- CRNKL1 | c.1413C>G p.I471M | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV101056929, COSV66106211; called by muse, mutect2, varscan2
- CRNN | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 28/175 reads (16%) | catalogued as COSV55120604; called by muse, varscan2
- CRTC1 | c.1281G>C p.E427D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV58720431; called by muse, mutect2, varscan2
- CRTC2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57841169, COSV57843903; called by muse, varscan2
- CRYBG3 | c.6187G>C p.D2063H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51710479, COSV51713455, COSV51716583; called by muse, mutect2, varscan2
- CSE1L | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53702940; called by muse, mutect2, varscan2
- CSPG4 | c.1508A>T p.K503M | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362478148, COSV57897563; called by muse, mutect2, varscan2
- CTAGE1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV66943886; called by muse, mutect2, varscan2
- CTR9 | c.2732C>G p.S911C | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV63728964, COSV63729424; called by muse, mutect2, varscan2
- CTSS | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV64566560; called by muse, mutect2
- CUL9 | c.6263G>A p.C2088Y | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52730669; called by muse, mutect2, varscan2
- CXorf56 | c.384G>A p.V128= (on ENST00000536133 / NM_001170570.2; = p.V142= on NM_022101.4) | Splice Region (SNP) | VAF 37/160 reads (23%) | catalogued as COSV57438649; called by muse, mutect2, varscan2
- CYP1A2 | c.1344G>C p.M448I | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59660145; called by muse, mutect2, varscan2
- CYP20A1 | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100619094, COSV61909813; called by muse, mutect2, varscan2
- CYP2C9 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV53250187; called by muse, mutect2, varscan2
- DAAM1 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62837576; called by muse, mutect2, varscan2
- DCAF11 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV58109700; called by muse, mutect2, varscan2
- DCAKD | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60831760; called by muse, mutect2, varscan2
- DCC | c.217A>C p.K73Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV59113743; called by muse, mutect2, varscan2
- DCHS1 | c.3532C>G p.Q1178E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as COSV55038271; called by muse, mutect2, varscan2
- DCLRE1A | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV63749090; called by muse, mutect2, varscan2
- DCP1A | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as COSV53689338; called by muse, mutect2, varscan2
- DCTN1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 139/581 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs1293714867, COSV62620863; called by muse, mutect2, varscan2
- DDIT4 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV56577623, COSV56577804; called by muse, mutect2, varscan2
- DDX11 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs1180227710, COSV52506700; called by muse, mutect2
- DDX46 | c.2641C>T p.L881F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV62799926; called by muse, mutect2, varscan2
- DDX5 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.028); catalogued as COSV56750095; called by muse, mutect2, varscan2
- DEF8 | c.636G>C p.Q212H (on ENST00000268676 / NM_207514.3; = p.Q151H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV51920131; called by muse, mutect2
- DGKI | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 35/118 reads (30%) | catalogued as COSV55958948; called by muse, mutect2, varscan2
- DGLUCY | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV56367631; called by muse, mutect2, varscan2
- DHRS1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs766291638, COSV55384699, COSV99852376; called by muse, mutect2, varscan2
- DHRS12 | c.541C>T p.Q181* (on ENST00000444610 / NM_001377930.1; = p.Q132* on NM_024705.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV54472028; called by muse, mutect2, varscan2
- DHRS3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs765594786, COSV66108438; called by muse, mutect2, varscan2
- DHX29 | c.2663C>G p.S888* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52419315; called by muse, mutect2, varscan2
- DHX34 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV60896096; called by muse, mutect2, varscan2
- DIO1 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV59518259; called by muse, mutect2
- DIRAS3 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as rs774421885, COSV63970522, COSV63970902, COSV63970913; called by muse, mutect2, varscan2
- DIS3L | c.1690G>A p.E564K (on ENST00000319212 / NM_001143688.3; = p.E481K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV59913121; called by muse, mutect2, varscan2
- DIXDC1 | c.2032G>A p.E678K (on ENST00000440460 / NM_001037954.4; = p.E467K on NM_033425.4) | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555178116, COSV59462223, COSV59462480; called by muse, mutect2
- DLGAP4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.269); catalogued as rs369666332; called by muse, mutect2, varscan2
- DMAC2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 37/137 reads (27%) | catalogued as COSV55728847; called by muse, mutect2, varscan2
- DMXL2 | c.6922G>C p.E2308Q | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51849752; called by muse, mutect2, varscan2
- DNAH17 | c.11786G>C p.G3929A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67757478; called by muse, varscan2
- DNAH3 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54531591; called by muse, mutect2
- DNAH5 | c.6094G>A p.D2032N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54235989; called by muse, mutect2, varscan2
- DNAH5 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54235998; called by muse, mutect2, varscan2
- DNAH8 | c.1110G>C p.E370D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV59431368, COSV59459761; called by muse, mutect2, varscan2
- DNAJB1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs768130288, COSV54317227, COSV54317299; called by muse, mutect2, varscan2
- DNAJC1 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV65412059; called by muse, mutect2, varscan2
- DNM1L | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56775535; called by muse, mutect2, varscan2
- DNMBP | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV60628262; called by muse, mutect2, varscan2
- DNMBP | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.031); catalogued as rs766585897, COSV60628279; called by muse, mutect2, varscan2
- DNMT3A | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs745432645, COSV53062004; called by muse, mutect2
- DOCK10 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51419711, COSV99289761; called by muse, mutect2
- DOK3 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57253092; called by muse, varscan2
- DOK5 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV52822249; called by muse, mutect2, varscan2
- DOK6 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101234538, COSV66933467; called by muse, mutect2, varscan2
- DOP1B | c.5499G>C p.Q1833H | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as COSV67694037; called by muse, mutect2, varscan2
- DPF3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV63501042; called by muse, mutect2, varscan2
- DRC1 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs1300407487, COSV56532760; called by muse, mutect2, varscan2
- DSCAML1 | c.5178C>G p.I1726M (on ENST00000321322; = p.I1666M on NM_020693.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58395590, COSV58401062; called by muse, mutect2, varscan2
- DSG3 | c.1716G>C p.Q572H | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV57127567; called by muse, varscan2
- DSG3 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57127571; called by muse, mutect2, varscan2
- DSG4 | c.2992G>C p.G998R | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV57390450; called by muse, mutect2, varscan2
- DSP | c.5410C>T p.Q1804* | Nonsense Mutation (SNP) | VAF 49/166 reads (30%) | catalogued as COSV65793716; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV50051018, COSV50052041; called by muse, mutect2, varscan2
- DYRK1A | c.2032C>G p.Q678E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.585); catalogued as COSV58707586; called by muse, mutect2, varscan2
- EDC4 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV54646649; called by muse, mutect2, varscan2
- EDIL3 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as rs765088380, COSV56885602; called by muse, mutect2, varscan2
- EFCAB3 | c.942G>C p.K314N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV59503009; called by muse, mutect2, varscan2
- EFCAB6 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.129); catalogued as COSV53066332; called by muse, mutect2, varscan2
- EFL1 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV51607171; called by muse, mutect2, varscan2
- EGFLAM | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59307610; called by muse, mutect2
- EIF2A | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV56407621; called by muse, mutect2
- EIF2B5 | c.926C>G p.S309C (on ENST00000647909; = p.S301C on NM_003907.3) | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs1352915033, COSV56604973, COSV56606215; called by muse, mutect2, varscan2
- EIF2S1 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV53605864; called by muse, mutect2, varscan2
- EIF3I | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV61890059; called by muse, varscan2
- EIF4A1 | c.996G>A p.L332= | Splice Region (SNP) | VAF 23/99 reads (23%) | catalogued as COSV51511322; called by muse, mutect2, varscan2
- ELL3 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55857114; called by muse, mutect2, varscan2
- ELMO3 | c.1186G>C p.E396Q (on ENST00000652269; = p.E343Q on NM_024712.5) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62607026; called by muse, mutect2, varscan2
- ELP1 | c.3590G>A p.R1197H | Missense Mutation (SNP) | VAF 85/414 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886063345, COSV65898468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENTPD7 | c.1662C>G p.F554L | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV65112605; called by muse, mutect2, varscan2
- EPB41 | c.868C>G p.P290A (on ENST00000343067 / NM_001166005.2; = p.P81A on NM_004437.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1051352050, COSV100548111, COSV58049788; called by muse, mutect2, varscan2
- EPG5 | c.6269C>T p.S2090F | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.488); catalogued as rs757874630, COSV56351899; called by muse, varscan2
- EPG5 | c.4996C>T p.Q1666* | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | catalogued as COSV56351918; called by muse, mutect2, varscan2
- EPHA2 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV64453771; called by muse, mutect2, varscan2
- EPHB6 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67419297; called by muse, mutect2, varscan2
- EPPK1 | c.1562C>G p.S521* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV73261711; called by muse, mutect2, varscan2
- ERC1 | c.2518G>C p.E840Q (on ENST00000360905 / NM_178040.4; = p.E812Q on NM_178039.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV61696765; called by muse, varscan2
- ERC1 | c.2574G>A p.M858I (on ENST00000360905 / NM_178040.4; = p.M830I on NM_178039.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV61696767, COSV61696993; called by muse, varscan2
- ERCC6L | c.1731G>C p.E577D | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV57821291; called by muse, mutect2, varscan2
- ERF | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV55896594; called by muse, mutect2, varscan2
- ESPN | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV64704707; called by muse, varscan2
- ESYT2 | c.2204G>A p.R735K (on ENST00000613624; = p.R659K on NM_020728.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV51752914; called by muse, mutect2, varscan2
- ETV5 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.562); catalogued as COSV60503743; called by muse, mutect2, varscan2
- EVL | c.1069C>G p.Q357E (on ENST00000402714 / NM_001330221.2; = p.Q359E on NM_016337.3) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.585); catalogued as COSV67376083; called by muse, mutect2, varscan2
- EXOC1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV62120881; called by muse, mutect2, varscan2
- EXOC6 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV53327352; called by muse, mutect2, varscan2
- EXOC8 | c.1428C>G p.I476M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV50478580; called by muse, varscan2
- EXOC8 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV50478582, COSV50478824; called by muse, varscan2
- EXOSC9 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.473); catalogued as COSV54666698; called by muse, mutect2, varscan2
- F11R | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV57038734; called by muse, mutect2, varscan2
- F13B | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV66374551; called by muse, mutect2, varscan2
- F7 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV60646718; called by muse, mutect2, varscan2
- FAHD2A | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV51978565; called by muse, mutect2, varscan2
- FAM102A | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); catalogued as rs532794999, COSV66194197; called by muse, mutect2, varscan2
- FAM13A | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV52006045; called by muse, mutect2, varscan2
- FAM171A1 | c.2192G>A p.G731E | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as COSV65317333; called by muse, mutect2, varscan2
- FAM209B | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100991027, COSV64915378; called by muse, mutect2, varscan2
- FAM50B | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV66654916, COSV66655024; called by muse, mutect2, varscan2
- FAM53B | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV55103109, COSV99784822; called by muse, mutect2, varscan2
- FAM71F2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV66352253; called by muse, mutect2, varscan2
- FAM83B | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60923848; called by muse, mutect2, varscan2
- FANK1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64158570; called by muse, mutect2, varscan2
- FARP2 | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV50873818, COSV50873852; called by muse, mutect2, varscan2
- FASLG | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV60680391; called by muse, mutect2, varscan2
- FASTKD1 | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); catalogued as COSV71624122, COSV71624429; called by muse, varscan2
- FAT2 | c.11626C>A p.L3876I | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.334); catalogued as COSV55823394; called by muse, mutect2, varscan2
- FAT2 | c.4154C>G p.S1385* | Nonsense Mutation (SNP) | VAF 42/165 reads (25%) | catalogued as COSV55816706, COSV55831000; called by muse, mutect2, varscan2
- FAT2 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV55818798, COSV55823429; called by muse, mutect2, varscan2
- FBXL20 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV52900723; called by muse, mutect2, varscan2
- FBXO42 | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 98/354 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65046153; called by muse, mutect2, varscan2
- FBXW2 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV61597398; called by muse, mutect2, varscan2
- FCGR2C | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as rs779861801, COSV63438836; called by muse, mutect2, varscan2
- FCHO2 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV55109538, COSV99821754; called by muse, mutect2, varscan2
- FCHSD1 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.326); catalogued as COSV51837857; called by muse, mutect2, varscan2
- FCRL6 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58940914, COSV58941558; called by muse, mutect2, varscan2
- FEZ1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430774054, COSV54029742; called by muse, mutect2, varscan2
- FGA | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57397654, COSV57398063, COSV57399544; called by muse, mutect2, varscan2
- FGD6 | c.2740G>C p.E914Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100676549, COSV59694477; called by muse, mutect2, varscan2
- FGF17 | c.336G>C p.K112N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.283); catalogued as COSV63925671; called by muse, mutect2, varscan2
- FGF2 | c.477C>G p.F159L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as COSV52651050; called by muse, mutect2, varscan2
- FIG4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57788822; called by muse, mutect2, varscan2
- FILIP1L | c.955C>G p.Q319E (on ENST00000354552 / NM_182909.3; = p.Q79E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV58764535, COSV58771472; called by muse, mutect2, varscan2
- FIP1L1 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1363321246, COSV60997738; called by muse, mutect2, varscan2
- FKBP5 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as COSV61882520; called by muse, mutect2, varscan2
- FLG2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV66170072; called by muse, mutect2, varscan2
- FLNC | c.1949G>C p.R650P | Missense Mutation (SNP) | VAF 80/386 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.403); catalogued as COSV57958663; called by muse, mutect2, varscan2
- FMO5 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.257); catalogued as rs1355592356, COSV54208193; called by muse, mutect2, varscan2
- FMR1NB | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV63272835; called by muse, mutect2, varscan2
- FNTA | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56490511; called by muse, mutect2, varscan2
- FOLR1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 37/158 reads (23%) | catalogued as COSV56616464; called by muse, varscan2
- FOXK1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs767698529, COSV61066980; called by muse, mutect2, varscan2
- FOXRED2 | c.1625-1G>A p.X542_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV53400646; called by muse, mutect2, varscan2
- FRMPD3 | c.3783G>C p.Q1261H | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52193143; called by muse, mutect2, varscan2
- FSTL5 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV60206001; called by muse, mutect2, varscan2
- GABPB1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55016070; called by muse, mutect2, varscan2
- GABRR1 | c.656-1G>A p.X219_splice | Splice Site (SNP) | VAF 30/182 reads (16%) | catalogued as COSV65619817, COSV65620079; called by muse, mutect2
- GALNT14 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV61107232; called by muse, mutect2, varscan2
- GALNTL5 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs775985027, COSV67180503; called by muse, mutect2, varscan2
- GAPDH | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as COSV57520441, COSV57521500; called by muse, mutect2, varscan2
- GATA1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.164); catalogued as rs1317593957, COSV64961764; called by muse, mutect2, varscan2
- GATAD2B | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64084754; called by muse, mutect2, varscan2
- GCN1 | c.6946G>C p.D2316H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324507, COSV56110265; called by muse, mutect2
- GCN1 | c.6631G>T p.E2211* | Nonsense Mutation (SNP) | VAF 10/149 reads (7%) | catalogued as COSV56108392; called by muse, mutect2
- GDF5 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as rs768083495, COSV65499791; called by muse, mutect2, varscan2
- GEMIN4 | c.2949C>G p.F983L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56746457, COSV56747861; called by muse, mutect2, varscan2
- GHDC | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs369509799; called by muse, mutect2, varscan2
- GIGYF2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as COSV65251045; called by muse, mutect2, varscan2
- GLIS2 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52111043; called by muse, varscan2
- GLIS2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs751337333, COSV52109508; called by muse, varscan2
- GMDS | c.1098G>C p.M366I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV101070644, COSV66416439; called by muse, mutect2, varscan2
- GMPR | c.896G>C p.G299A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52474054; called by muse, mutect2, varscan2
- GMPS | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs1339812781, COSV55810377, COSV99903351; called by muse, mutect2, varscan2
- GNB3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs150593798; called by muse, mutect2, varscan2
- GNL1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV64835355; called by muse, mutect2, varscan2
- GNPTAB | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV68449723; called by muse, mutect2, varscan2
- GOLGB1 | c.7306G>C p.D2436H | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV61467510; called by muse, mutect2, varscan2
- GON4L | c.4195G>A p.E1399K | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.118); catalogued as COSV55196898; called by muse, mutect2, varscan2
- GPR35 | c.762C>G p.I254M | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV60577731; called by muse, mutect2, varscan2
- GPRASP1 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 47/174 reads (27%) | catalogued as COSV64354689, COSV64355331; called by muse, mutect2, varscan2
- GPRC6A | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775109241, COSV59951289; called by muse, mutect2, varscan2
- GRAMD2A | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59034175; called by muse, mutect2, varscan2
- GRID1 | c.1776G>C p.Q592H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV60037490; called by muse, mutect2, varscan2
- GRIK1 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58723334; called by mutect2, varscan2
- GRIN2B | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV74206605; called by muse, mutect2, varscan2
- GRIP1 | c.2506G>A p.D836N (on ENST00000359742 / NM_001379345.1; = p.D784N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/361 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs765335569, COSV54030186, COSV54043017; called by muse, mutect2, varscan2
- GSPT2 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.477); catalogued as COSV61214610; called by muse, mutect2
- GTF2IRD1 | c.2880G>C p.*960Yext*13 (on ENST00000265755 / NM_016328.3; = p.*945Yext*13 on NM_005685.4) | Nonstop Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as COSV56088341; called by muse, mutect2, varscan2
- GTPBP2 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.338); catalogued as COSV61076712; called by muse, mutect2, varscan2
- GTPBP6 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1029767262, COSV58205296; called by muse, mutect2, varscan2
- H1-1 | c.444G>C p.K148N | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV55119884; called by muse, mutect2, varscan2
- H2AC21 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV58612454; called by muse, mutect2, varscan2
- H2BC10 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100010408, COSV59952776, COSV59953804; called by muse, varscan2
- H4C6 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as rs757826768, COSV66685393; called by muse, mutect2, varscan2
- HAAO | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54311648; called by muse, mutect2, varscan2
- HABP4 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV64514974; called by muse, mutect2, varscan2
- HACD1 | c.606-1G>A p.X202_splice | Splice Site (SNP) | VAF 17/75 reads (23%) | catalogued as COSV63516613, COSV63516638; called by muse, mutect2, varscan2
- HACL1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406749192, COSV58255143; called by muse, mutect2, varscan2
- HAS3 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV54707797; called by muse, mutect2, varscan2
- HAUS5 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52548515; called by muse, varscan2
- HAVCR2 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV57153580; called by muse, mutect2, varscan2
- HDAC9 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV67777093; called by muse, mutect2
- HDLBP | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60497967; called by muse, mutect2, varscan2
- HEATR3 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV53530111; called by muse, mutect2
- HEATR5B | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768615339, COSV51854874; called by muse, mutect2, varscan2
- HELZ2 | c.2243C>T p.A748V (on ENST00000467148 / NM_001037335.2; = p.A179V on NM_033405.3) | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV64409970; called by muse, mutect2, varscan2
- HIRA | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as COSV54276624; called by muse, mutect2, varscan2
- HIVEP1 | c.5299G>C p.D1767H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65103017; called by muse, mutect2, varscan2
- HJURP | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV68578823; called by muse, mutect2, varscan2
- HLA-DMB | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.082); catalogued as COSV101186814, COSV66870846; called by muse, mutect2, varscan2
- HMBOX1 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as rs764079365, COSV55069796; called by muse, mutect2, varscan2
- HMCN1 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV54913950; called by muse, mutect2, varscan2
- HMGCS1 | c.1106G>C p.R369T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57290660; called by muse, mutect2, varscan2
- HMOX1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53340497; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.409); catalogued as rs757332292, COSV61255636; called by mutect2, varscan2
- HORMAD1 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 21/118 reads (18%) | catalogued as COSV55046816; called by muse, mutect2, varscan2
- HOXA2 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as COSV56066988; called by muse, mutect2, varscan2
- HRH2 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV51574870; called by muse, mutect2, varscan2
- HRNR | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV64259860; called by muse, mutect2, varscan2
- HS6ST2 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV63714909; called by muse, mutect2, varscan2
- HSD17B11 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64154726; called by muse, mutect2, varscan2
- HSD17B4 | c.721G>C p.E241Q (on ENST00000414835 / NM_001199291.3; = p.E216Q on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV56337044; called by muse, mutect2, varscan2
- HSF4 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV50457975; called by muse, mutect2, varscan2
- HTR1A | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146873107; called by muse, varscan2
- HTT | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1484295109, COSV61864749; called by muse, mutect2, varscan2
- HTT | c.4675G>A p.D1559N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61864757; called by muse, mutect2, varscan2
- HYAL1 | c.1233G>C p.Q411H | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.244); catalogued as COSV56498456; called by muse, mutect2, varscan2
- HYDIN | c.14009G>C p.W4670S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66639974; called by muse, mutect2, varscan2
- ICA1 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV55580830, COSV55584444; called by muse, mutect2, varscan2
- IFI44 | c.522G>C p.L174F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV66075093; called by muse, mutect2, varscan2
- IFNAR2 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV51616420; called by muse, mutect2
- IFNL2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV59593695; called by muse, mutect2, varscan2
- IKZF1 | c.1532G>C p.R511P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58781328, COSV58788249; called by muse, mutect2, varscan2
- IL15RA | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs781024557, COSV66092666, COSV66092901; called by muse, mutect2, varscan2
- IL37 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as COSV54491772; called by muse, mutect2
- IL3RA | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.425); catalogued as COSV58432109; called by muse, mutect2, varscan2
- IL5RA | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56524668; called by muse, mutect2, varscan2
- INPP1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59416501; called by muse, mutect2, varscan2
- INTS2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV52151044, COSV52154277; called by muse, mutect2, varscan2
- INTS3 | c.2388C>G p.L796= | Splice Region (SNP) | VAF 15/101 reads (15%) | catalogued as COSV55164409; called by muse, mutect2, varscan2
- IPO13 | c.1999A>C p.K667Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV64894654; called by muse, mutect2, varscan2
- IPO9 | c.2434C>G p.L812V | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64234313; called by muse, mutect2, varscan2
- IQCH | c.1265C>G p.S422* | Nonsense Mutation (SNP) | VAF 42/211 reads (20%) | catalogued as COSV60055602; called by muse, mutect2, varscan2
- IRAG1 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.745); catalogued as COSV70211868; called by muse, mutect2, varscan2
- IRF2 | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66929825; called by muse, mutect2, varscan2
- IRF6 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65419649; called by muse, mutect2, varscan2
- ITGAV | c.1990C>G p.Q664E | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.224); catalogued as COSV53711969, COSV53714807; called by muse, mutect2, varscan2
- ITGB3 | c.1188C>G p.F396L | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV71384437; called by muse, mutect2, varscan2
- ITGB4 | c.2962+1G>C p.X988_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as rs113310826, COSV52328846; called by muse, mutect2, varscan2
- ITSN1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66084176; called by muse, mutect2, varscan2
- ITSN2 | c.3152C>T p.S1051L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV61949861; called by muse, mutect2, varscan2
- JADE2 | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV50920503; called by muse, mutect2, varscan2
- JAK2 | c.2653C>A p.Q885K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.614); catalogued as COSV101078346, COSV67629302; called by muse, mutect2, varscan2
- KCNA1 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV101230087, COSV66837421; called by muse, mutect2, varscan2
- KCNA1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs543311674, COSV66837931; called by muse, mutect2, varscan2
- KCNJ14 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV57309796, COSV57310285; called by muse, mutect2, varscan2
- KDM3B | c.3691C>T p.Q1231* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as COSV58692406; called by muse, mutect2, varscan2
- KDM5A | c.955C>G p.H319D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238765, COSV66993887; called by muse, mutect2, varscan2
- KDM5A | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs746045026, COSV66993896; called by muse, mutect2, varscan2
- KIDINS220 | c.1976C>G p.S659C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV56753030; called by muse, mutect2
- KIF15 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58162323; called by muse, mutect2, varscan2
- KIF16B | c.3334C>T p.P1112S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.197); catalogued as COSV61708619; called by muse, mutect2, varscan2
- KIF21A | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567275114, COSV62773933; called by muse, mutect2, varscan2
- KIRREL1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs763574141, COSV63288628; called by muse, mutect2, varscan2
- KLF10 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV53436001; called by muse, mutect2, varscan2
- KLHL13 | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV53249726; called by muse, mutect2, varscan2
- KMO | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 24/202 reads (12%) | catalogued as COSV63809227; called by muse, mutect2
- KMT2C | c.11069C>G p.S3690* | Nonsense Mutation (SNP) | VAF 91/385 reads (24%) | catalogued as COSV51459200; called by muse, mutect2, varscan2
- KMT2C | c.10021C>A p.P3341T | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV51459242; called by muse, mutect2, varscan2
- KMT2C | c.3443C>G p.S1148* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV51459269, COSV51497608; called by muse, mutect2, varscan2
- KMT2D | c.12850C>T p.Q4284* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV56457449; called by muse, mutect2
- KPNA2 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 116/480 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV57858164; called by muse, mutect2, varscan2
- KPNA3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV55505653; called by muse, mutect2, varscan2
- KRT1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52867611; called by muse, mutect2, varscan2
- KRT31 | c.1216C>G p.P406A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV52436245; called by muse, mutect2, varscan2
- KRT86 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV53291747, COSV53293282; called by muse, mutect2, varscan2
- KYAT3 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53102898; called by muse, mutect2, varscan2
- LAMA1 | c.3922G>A p.E1308K | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV67539536; called by muse, mutect2, varscan2
- LAMA4 | c.4822-1G>C p.X1608_splice (on ENST00000230538 / NM_001105206.3; = p.X1601_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/86 reads (27%) | catalogued as COSV57900059; called by muse, mutect2, varscan2
- LAMP3 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55615546; called by muse, mutect2
- LAMTOR1 | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53826104; called by muse, mutect2
- LATS1 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53593815; called by muse, mutect2, varscan2
- LCAT | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV50453189; called by muse, varscan2
- LCE1B | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.757); catalogued as rs763223529, COSV63980425; called by muse, mutect2, varscan2
- LCP2 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV50453940, COSV50454264; called by muse, mutect2, varscan2
- LEFTY1 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as COSV55283443; called by muse, mutect2, varscan2
- LIG1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54393386; called by muse, mutect2, varscan2
- LILRB4 | c.739G>C p.G247R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV54406547, COSV54408551; called by muse, mutect2, varscan2
- LIMK1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100283190, COSV60282689; called by muse, mutect2, varscan2
- LIN28A | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV54262304; called by muse, mutect2, varscan2
- LIPF | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as COSV53284780; called by muse, mutect2, varscan2
- LLGL2 | c.76-1G>A p.X26_splice | Splice Site (SNP) | VAF 26/108 reads (24%) | catalogued as COSV51364300; called by muse, mutect2, varscan2
- LMBRD1 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV65298065; called by muse, mutect2, varscan2
- LMF2 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV53318078; called by muse, mutect2
- LMX1A | c.1067C>G p.S356* | Nonsense Mutation (SNP) | VAF 40/270 reads (15%) | catalogued as COSV54223522; called by muse, mutect2, varscan2
- LMX1A | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV54223533; called by muse, mutect2
- LNX2 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV60336748; called by muse, mutect2
- LONRF3 | c.1541C>G p.S514* (on ENST00000371628 / NM_001031855.3; = p.S473* on NM_024778.5) | Nonsense Mutation (SNP) | VAF 21/124 reads (17%) | catalogued as COSV59151998; called by muse, mutect2, varscan2
- LPO | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as rs773890218, COSV51860240; called by muse, mutect2, varscan2
- LRFN5 | c.2018C>G p.S673* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV53263890, COSV53269559; called by muse, mutect2, varscan2
- LRP5 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV53718403; called by muse, mutect2, varscan2
- LRRC1 | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV63829781; called by muse, mutect2, varscan2
- LRRC31 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52979439; called by muse, mutect2, varscan2
- LRRC31 | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV52981524; called by muse, mutect2, varscan2
- LSM5 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs376563041; called by mutect2, varscan2
- LTBP4 | c.766G>A p.E256K (on ENST00000308370 / NM_001042544.1; = p.E219K on NM_003573.2) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV52584764; called by muse, varscan2
- LYPD3 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54989044, COSV54989068; called by muse, mutect2, varscan2
- LYST | c.4295C>T p.S1432L | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1558251278, COSV67709242; called by muse, mutect2, varscan2
- LYZL1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV100973677, COSV64966640; called by muse, mutect2, varscan2
- M6PR | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50003251; called by muse, mutect2, varscan2
- MAGEA11 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 101/543 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV60756890, COSV60758990; called by muse, mutect2, varscan2
- MAGI3 | c.3305G>A p.G1102E | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56838863; called by muse, varscan2
- MANBA | c.1672G>A p.E558K (on ENST00000642252; = p.E512K on NM_005908.4) | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV56967083; called by muse, mutect2, varscan2
- MANBA | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV56967092; called by muse, varscan2
- MAOA | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58643814; called by muse, mutect2, varscan2
- MAP1B | c.4906C>T p.Q1636* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV57101611; called by muse, mutect2, varscan2
- MAP1LC3A | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1357145981, COSV54159932; called by muse, mutect2, varscan2
- MAP3K5 | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62890100; called by muse, mutect2, varscan2
- MAP3K8 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV53920512, COSV53921331; called by muse, mutect2, varscan2
- MARCO | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV59055785; called by muse, mutect2, varscan2
- MAST3 | c.2329C>G p.L777V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs776658150, COSV53222859; called by muse, mutect2, varscan2
- MAST4 | c.2587G>C p.E863Q (on ENST00000403625 / NM_001164664.2; = p.E674Q on NM_015183.3) | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55131194; called by muse, mutect2, varscan2
- MBTD1 | c.579G>C p.W193C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64503795; called by muse, mutect2, varscan2
- MC5R | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61255023; called by muse, mutect2, varscan2
- MCF2L | c.2815G>A p.E939K (on ENST00000375608; = p.E907K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56179112; called by muse, mutect2, varscan2
- MCM8 | c.2342C>G p.S781C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV54515758; called by muse, mutect2, varscan2
- MCTP2 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs201364128; called by muse, mutect2, varscan2
- MCUR1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774710482, COSV63958051; called by muse, mutect2, varscan2
- MECP2 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as CD124041, CM003458, COSV57655117; called by muse, mutect2, varscan2
- MED1 | c.3146C>G p.S1049C | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56126342; called by muse, mutect2, varscan2
- MEGF10 | c.1013C>A p.A338E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as rs934709669, COSV57252203; called by muse, mutect2, varscan2
- MFAP4 | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV55191002; called by muse, mutect2, varscan2
- MFSD12 | c.146C>G p.S49W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as COSV62598062, COSV62598163; called by muse, mutect2
- MFSD8 | c.1350G>A p.Q450= | Splice Region (SNP) | VAF 35/130 reads (27%) | catalogued as rs796052738, COSV56551743; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAT2 | c.581G>C p.R194T | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV53566578; called by muse, mutect2, varscan2
- MIA2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV54484472; called by muse, mutect2, varscan2
- MICALL1 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs141260509; called by muse, mutect2, varscan2
- MIER1 | c.292G>A p.D98N (on ENST00000355356 / NM_001077701.3; = p.D115N on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as COSV62530872; called by muse, mutect2, varscan2
- MKRN3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1461939355, COSV58808468, COSV58808530; called by muse, mutect2, varscan2
- MLLT10 | c.2336C>T p.S779L (on ENST00000307729 / NM_001195626.3; = p.S795L on NM_004641.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1485908140, COSV56999119; called by muse, mutect2, varscan2
- MLLT3 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 115/489 reads (24%) | catalogued as COSV63498882; called by muse, mutect2, varscan2
- MLXIPL | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1554597763, COSV100515223, COSV57668953; called by muse, mutect2
- MMAB | c.225G>C p.R75S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV57170588; called by muse, mutect2, varscan2
- MMEL1 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs1303896661, COSV56523000; called by muse, mutect2, varscan2
- MMGT1 | c.383C>G p.S128* | Nonsense Mutation (SNP) | VAF 74/323 reads (23%) | catalogued as COSV100018420, COSV60003666; called by muse, mutect2, varscan2
- MMP16 | c.1334G>A p.W445* | Nonsense Mutation (SNP) | VAF 30/154 reads (19%) | catalogued as COSV54173701; called by muse, mutect2, varscan2
- MMP26 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV56172794; called by muse, mutect2, varscan2
- MON1A | c.1821G>A p.V607= | Splice Region (SNP) | VAF 17/73 reads (23%) | catalogued as rs763859651, COSV56561383; called by muse, mutect2, varscan2
- MOV10 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV62491830; called by muse, mutect2, varscan2
- MRPL18 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51706291; called by muse, mutect2, varscan2
- MRPL35 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs773669532, COSV54487906; called by muse, mutect2, varscan2
- MSL3 | c.1383G>T p.V461= (on ENST00000312196 / NM_078629.4; = p.V295= on NM_006800.4) | Splice Region (SNP) | VAF 21/112 reads (19%) | catalogued as COSV56491269, COSV56494263; called by muse, mutect2, varscan2
- MTFR1 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV50952072; called by muse, mutect2, varscan2
- MTSS1 | c.1649G>C p.R550T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52675431; called by muse, mutect2, varscan2
- MTTP | c.2511C>T p.F837= | Splice Region (SNP) | VAF 43/214 reads (20%) | catalogued as COSV55507404; called by muse, mutect2, varscan2
- MUC13 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV60700206; called by muse, mutect2, varscan2
- MUC16 | c.38455C>G p.Q12819E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67476610; called by muse, mutect2, varscan2
- MUC17 | c.11212C>G p.L3738V | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); catalogued as COSV60293979; called by muse, mutect2, varscan2
- MUC5AC | c.13688C>G p.S4563C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.08); catalogued as COSV64369764; called by muse, mutect2, varscan2
- MUC5B | c.11670G>C p.W3890C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV101500947, COSV71593720; called by muse, mutect2, varscan2
- MUC6 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as COSV70144599; called by muse, mutect2, varscan2
- MYBPC2 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV63097022; called by muse, mutect2, varscan2
- MYCBP2 | c.12044G>C p.R4015T (on ENST00000357337; = p.R4053T on NM_015057.5) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62026914; called by muse, mutect2
- MYH13 | c.5236G>C p.E1746Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52833864; called by muse, mutect2, varscan2
- MYH15 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56313643; called by muse, mutect2, varscan2
- MYH3 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV56866873, COSV99878738; called by muse, mutect2, varscan2
- MYH9 | c.4801G>T p.E1601* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as COSV53388879; called by muse, mutect2, varscan2
- MYH9 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV53388892; called by muse, mutect2, varscan2
- MYLK4 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs924230351, COSV51144590; called by muse, mutect2, varscan2
- MYO10 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57024768; called by muse, mutect2, varscan2
- MYO1G | c.469C>G p.H157D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51855465; called by muse, mutect2, varscan2
- MYO9A | c.2336C>G p.S779C | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV61853489; called by muse, mutect2, varscan2
- MYOT | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53515331; called by muse, mutect2, varscan2
- N6AMT1 | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100375114; called by muse, mutect2
- NASP | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs1233624420, COSV63113684; called by muse, mutect2, varscan2
- NBEAL1 | c.7755C>G p.I2585M | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV68916359; called by muse, mutect2, varscan2
- NBR1 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV57833594; called by muse, mutect2, varscan2
- NCAM2 | c.777G>C p.L259F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.833); catalogued as COSV53085482; called by muse, mutect2, varscan2
- NCAPD2 | c.3959C>G p.S1320C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV57520490, COSV57521491; called by muse, mutect2, varscan2
- NCAPH2 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV53219003; called by muse, mutect2, varscan2
- NCKAP1L | c.2670G>C p.L890F | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV53208846; called by muse, mutect2, varscan2
- NDST2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.998); catalogued as COSV55215947; called by muse, mutect2
- NDST3 | c.2137G>C p.D713H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56622476; called by muse, mutect2, varscan2
- NECTIN3 | c.1429C>G p.P477A | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as COSV60552164; called by muse, mutect2, varscan2
- NEK4 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as COSV51781323; called by muse, mutect2, varscan2
- NEK5 | c.1521G>C p.K507N | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV62880785; called by muse, mutect2, varscan2
- NEK5 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV62880792, COSV62880818; called by muse, mutect2, varscan2
- NEO1 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as COSV56073982; called by muse, mutect2, varscan2
- NETO1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55009509; called by muse, mutect2, varscan2
- NEXMIF | c.4516G>C p.E1506Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV50022375, COSV50046392, COSV50163697; called by muse, mutect2, varscan2
- NF2 | c.1672C>G p.L558V | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); catalogued as rs765386271, COSV58525964; called by muse, mutect2, varscan2
- NFATC3 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.984); catalogued as COSV60475763; called by muse, mutect2, varscan2
- NFE2L2 | c.1544G>C p.R515T | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67961554; called by muse, mutect2, varscan2
- NFYA | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV58199085; called by muse, mutect2, varscan2
- NIBAN1 | c.2777C>T p.S926L | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs769217969, COSV62285947; called by muse, mutect2, varscan2
- NIN | c.6116G>A p.R2039Q (on ENST00000382041 / NM_182946.1; = p.R1326Q on NM_016350.4) | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774918630, COSV55396313; called by muse, mutect2, varscan2
- NINL | c.746G>C p.G249A | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV54004829, COSV99626352; called by muse, mutect2
- NLGN4X | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.285); catalogued as COSV52005672, COSV52025070; called by muse, mutect2, varscan2
- NLRP7 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769310230, COSV60176813; called by muse, mutect2, varscan2
- NLRP9 | c.2621G>A p.R874K | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1403381962, COSV60461904, COSV60465034; called by muse, mutect2, varscan2
- NOD2 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.997); catalogued as COSV56052452; called by muse, mutect2, varscan2
- NOLC1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 86/373 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV64180683; called by muse, mutect2, varscan2
- NOS2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 32/171 reads (19%) | catalogued as COSV58225204; called by muse, mutect2, varscan2
- NOTCH2 | c.7281T>G p.S2427R | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56695581; called by muse, mutect2, varscan2
- NOX3 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV50151977; called by muse, mutect2, varscan2
- NPHS1 | c.2867C>T p.S956F | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866384002, COSV62286653; called by muse, mutect2, varscan2
- NPY1R | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs753896952, COSV56713995, COSV56714699, COSV56715449; called by muse, mutect2, varscan2
- NR2E1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV64561211, COSV64561259; called by muse, mutect2, varscan2
- NR5A2 | c.238G>A p.E80K (on ENST00000367362 / NM_205860.3; = p.E34K on NM_003822.5) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.104); catalogued as COSV52653045; called by muse, mutect2, varscan2
- NT5C2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.08); catalogued as COSV58417454; called by muse, mutect2, varscan2
- NUAK1 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV54605095; called by muse, mutect2, varscan2
- NUCB1 | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54386901; called by muse, mutect2, varscan2
- NUP210L | c.3862G>C p.E1288Q | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55151143; called by muse, mutect2, varscan2
- NUTM2A | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV67742006; called by mutect2, varscan2
- NWD1 | c.4661C>G p.S1554* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60345301; called by muse, mutect2
- OGDHL | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as COSV104427168, COSV65103355; called by muse, mutect2, varscan2
- OLA1 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52971622; called by muse, mutect2, varscan2
- OLFM2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV53431711; called by muse, mutect2, varscan2
- OR10K2 | c.639G>C p.L213F | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV59220500, COSV59221753; called by muse, mutect2, varscan2
- OR11H12 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV73543697; called by muse, mutect2, varscan2
- OR13C2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73377674; called by muse, mutect2, varscan2
- OR2G6 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV58575013, COSV58575189; called by muse, mutect2, varscan2
- OR2V2 | c.474G>C p.L158F | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.529); catalogued as COSV60314718; called by muse, mutect2, varscan2
- OR4A16 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59043897; called by muse, mutect2, varscan2
- OR51D1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV62913870, COSV62914369; called by muse, mutect2, varscan2
- OR52D1 | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59487836; called by muse, mutect2, varscan2
- OR52N1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV57693388; called by muse, mutect2, varscan2
- OR5T3 | c.816G>C p.M272I | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV57381051, COSV57381505; called by muse, mutect2, varscan2
- OR6C65 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV65568900; called by muse, mutect2, varscan2
- ORC4 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51574878; called by muse, mutect2, varscan2
- OS9 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV57783678; called by muse, mutect2, varscan2
- OSBPL11 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV56172822, COSV56174760; called by muse, mutect2, varscan2
- OVCH2 | c.348C>G p.D116E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71952900; called by muse, mutect2, varscan2
- OXSM | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV55002029, COSV55002406; called by muse, mutect2, varscan2
- P2RY4 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65736825; called by muse, mutect2, varscan2
- PABPC3 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55802524; called by muse, varscan2
- PACSIN2 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV54320758; called by muse, mutect2, varscan2
- PANK3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as rs376150396; called by muse, mutect2, varscan2
- PAPPA2 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 85/468 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV62780981; called by muse, mutect2, varscan2
- PAPPA2 | c.2659G>A p.D887N | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV62772852, COSV62780990; called by muse, mutect2, varscan2
- PAPPA2 | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752126396, COSV62798211; called by muse, mutect2, varscan2
- PARP14 | c.3740C>G p.S1247* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV71734236, COSV71735002; called by muse, mutect2, varscan2
- PCDH15 | c.3368C>G p.S1123* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as COSV57341144; called by muse, mutect2, varscan2
- PCDH15 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as COSV57341182; called by muse, mutect2, varscan2
- PCDHA10 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.16); catalogued as rs193920994, COSV56487682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB6 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV50697872, COSV50704843; called by muse, mutect2, varscan2
- PCLO | c.11341C>T p.R3781* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as rs865939646, COSV61646028; called by muse, mutect2, varscan2
- PCLO | c.6844G>A p.E2282K | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs752151120, COSV61646039; called by muse, varscan2
- PCLO | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV61646076; called by muse, mutect2, varscan2
- PCNX2 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.522); catalogued as COSV50820969; called by muse, mutect2, varscan2
- PCSK6 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.136); catalogued as COSV59342262; called by muse, mutect2, varscan2
- PCYT1A | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as COSV53058364; called by muse, mutect2, varscan2
- PDS5A | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV57827689; called by muse, mutect2, varscan2
- PDZD2 | c.7505C>G p.S2502* | Nonsense Mutation (SNP) | VAF 40/157 reads (25%) | catalogued as COSV56863186; called by muse, mutect2, varscan2
- PDZD3 | c.1307C>T p.S436L (on ENST00000531114; = p.S356L on NM_024791.4) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1419795033, COSV52704239; called by muse, mutect2, varscan2
- PDZD4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV51248022; called by muse, mutect2, varscan2
- PELO | c.1142G>C p.S381T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.827); catalogued as COSV50886344; called by muse, mutect2, varscan2
- PER3 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.801); catalogued as COSV62706580; called by muse, mutect2, varscan2
- PERP | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV69827607; called by muse, mutect2, varscan2
- PGBD5 | c.402G>A p.M134I (on ENST00000525115; = p.M203I on NM_001258311.2) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58412385; called by muse, mutect2, varscan2
- PGD | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV54622147; called by muse, mutect2, varscan2
- PHACTR2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV59855898; called by muse, mutect2, varscan2
- PHEX | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as COSV65076760; called by muse, mutect2
- PHRF1 | c.2752G>C p.E918Q (on ENST00000264555 / NM_001286581.2; = p.E917Q on NM_020901.4) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs749565622, COSV52758130; called by muse, mutect2, varscan2
- PIAS3 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV57907207; called by muse, mutect2, varscan2
- PIK3AP1 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | catalogued as rs35933944, COSV59534125; called by muse, mutect2, varscan2
- PIK3R1 | c.1675A>G p.I559V (on ENST00000521381 / NM_181523.3; = p.I289V on NM_181504.4) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV57132753; called by muse, mutect2, varscan2
- PITRM1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV56534180; called by muse, mutect2, varscan2
- PITX1 | c.806C>G p.S269W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54762506; called by muse, varscan2
- PKD1 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs770952448, COSV51919603; called by mutect2, varscan2
- PKD1L1 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV56970008; called by muse, mutect2, varscan2
- PKP1 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55822844; called by muse, mutect2
- PLCB4 | c.1943C>A p.S648* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV53807033; called by muse, mutect2, varscan2
- PLCL1 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV70843182, COSV70851373; called by muse, mutect2, varscan2
- PLEC | c.7837-1G>C p.X2613_splice (on ENST00000322810 / NM_201380.4; = p.X2503_splice on NM_000445.5) | Splice Site (SNP) | VAF 27/135 reads (20%) | catalogued as COSV59654787; called by muse, mutect2, varscan2
- PLEC | c.7014G>C p.Q2338H (on ENST00000322810 / NM_201380.4; = p.Q2228H on NM_000445.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59654899; called by mutect2, varscan2
- PLEC | c.6817G>C p.E2273Q (on ENST00000322810 / NM_201380.4; = p.E2163Q on NM_000445.5) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59654956; called by muse, mutect2, varscan2
- PLEKHG4B | c.730C>T p.H244Y (on ENST00000283426; = p.H600Y on NM_052909.5) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV52050109; called by muse, mutect2, varscan2
- PLEKHO2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV60262377; called by muse, mutect2, varscan2
- PLK4 | c.1830G>C p.V610= | Splice Region (SNP) | VAF 22/85 reads (26%) | catalogued as COSV54638257; called by muse, mutect2, varscan2
- PLS1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV61834495; called by muse, mutect2, varscan2
- PLVAP | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV53085114; called by muse, mutect2, varscan2
- PLXNB2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as COSV63782781; called by muse, mutect2, varscan2
- PLXNC1 | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51575978, COSV51578026; called by muse, mutect2, varscan2
- PM20D2 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51531174; called by muse, mutect2, varscan2
- PML | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.3); catalogued as COSV51449056; called by muse, mutect2, varscan2
- PNKP | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV59274791, COSV59276612; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV65048814; called by muse, mutect2, varscan2
- PNP | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 39/144 reads (27%) | catalogued as rs896550845, CM044240, COSV64092028; called by muse, mutect2, varscan2
- POLG | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as rs373316463, COSV51522911; called by muse, mutect2, varscan2
- POLR3B | c.2515C>T p.P839S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV57278559; called by muse, mutect2, varscan2
- POLRMT | c.2542C>G p.L848V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1178406345, COSV52116139; called by muse, mutect2, varscan2
- POLRMT | c.324G>C p.Q108H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV73933346; called by muse, mutect2, varscan2
- POMGNT2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as rs536444876, COSV60953691; called by muse, mutect2
- PORCN | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV58226569; called by muse, mutect2, varscan2
- POSTN | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV65713531; called by muse, mutect2, varscan2
- PPIG | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV53644119; called by muse, mutect2, varscan2
- PPM1J | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV58552280; called by muse, mutect2, varscan2
- PPP1CB | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as COSV56091054; called by muse, mutect2, varscan2
- PPP1R12A | c.2081G>C p.R694T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54110600; called by muse, mutect2, varscan2
- PPP1R8 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52580361; called by muse, mutect2, varscan2
- PPRC1 | c.4376C>A p.S1459Y | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV53386648; called by muse, mutect2, varscan2
- PPWD1 | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV54334327; called by muse, mutect2, varscan2
- PRAMEF14 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 8/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1289287280; called by muse, mutect2
- PROM2 | c.215C>G p.S72W | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV58299202; called by muse, mutect2, varscan2
- PRPF39 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV63277129; called by muse, mutect2, varscan2
- PRR30 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as COSV53206030; called by muse, mutect2, varscan2
- PRR5L | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61120074; called by muse, mutect2, varscan2
- PRRC2B | c.1873C>A p.P625T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61939231; called by muse, mutect2, varscan2
- PSD | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV50048482; called by mutect2, varscan2
- PSD2 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs959236903, COSV51199231, COSV51203252; called by muse, mutect2, varscan2
- PTCH1 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59481697; called by muse, mutect2, varscan2
- PTDSS2 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57278873; called by muse, mutect2, varscan2
- PTPRN2 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs752320947, COSV67046916; called by muse, mutect2, varscan2
- PTPRZ1 | c.4844-1G>C p.X1615_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as COSV66440427; called by muse, mutect2, varscan2
- PUM3 | c.83-1G>C p.X28_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | catalogued as COSV67396752; called by muse, mutect2, varscan2
- PXDN | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV53239055; called by muse, mutect2, varscan2
- PXK | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57090561; called by muse, mutect2, varscan2
- QPCTL | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.659); catalogued as rs376175267; called by muse, mutect2, varscan2
- QPCTL | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.779); catalogued as COSV50004157; called by muse, mutect2, varscan2
- RAB3D | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs1388837319, COSV55792275; called by muse, mutect2, varscan2
- RALGAPA1 | c.3928C>T p.H1310Y | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51888124; called by muse, mutect2, varscan2
- RARS2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV65761663; called by muse, mutect2, varscan2
- RASGRP4 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV53096324; called by muse, mutect2, varscan2
- RASSF3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV51684908; called by muse, mutect2, varscan2
- RB1CC1 | c.2501C>G p.S834* | Nonsense Mutation (SNP) | VAF 29/121 reads (24%) | catalogued as COSV50255164; called by muse, mutect2, varscan2
- RB1CC1 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV50255226; called by muse, mutect2, varscan2
- RBM15 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63923817; called by muse, varscan2
- RBM17 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs1045876438, COSV65914337; called by muse, mutect2, varscan2
- RBM26 | c.2305G>C p.D769H (on ENST00000438737 / NM_001366735.2; = p.D742H on NM_022118.5) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57396439; called by muse, mutect2, varscan2
- RBM33 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55298365; called by muse, mutect2
- RBM5 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61738134; called by muse, mutect2, varscan2
- RBM5 | c.1704G>C p.L568F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.056); catalogued as COSV61738137; called by muse, mutect2, varscan2
- RBSN | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV53794003; called by muse, mutect2, varscan2
- RCAN3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV65558682; called by muse, mutect2, varscan2
- RCSD1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV63259566; called by muse, mutect2, varscan2
- RERE | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.64); catalogued as rs755330175, COSV61944845, COSV61944955; called by muse, mutect2, varscan2
- RERE | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV61944962; called by muse, mutect2, varscan2
- REXO2 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | catalogued as COSV56277283; called by muse, mutect2, varscan2
- RFC1 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333670896, COSV62900181; called by muse, mutect2, varscan2
- RFPL3 | c.94G>C p.A32P (on ENST00000249007 / NM_001098535.1; = p.A3P on NM_006604.2) | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV50750633; called by muse, mutect2, varscan2
- RGL2 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs367652018, COSV69916607; called by muse, mutect2, varscan2
679 further variants in this file (308 protein-altering or splice-affecting, 340 silent, 31 other) are not listed here.
